Gene-level copy-number profile of tumor specimen ALCH-B4SX-TTP1-A from ALCHEMIST case ALCH-B4SX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.4 years (27,163 days).
Specimen ALCH-B4SX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e6e67fd5-a5f6-4449-bb67-e2276666ad81.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4SX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/2f5cd646-6ab0-410a-a657-7d98b20aa5de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 19,093; copy number 2: 38,371; copy number 3: 813; copy number 4: 487; copy number 5: 49; copy number 6: 2; copy number 7: 7; copy number 8: 4; copy number 10: 4; copy number 11: 7; copy number 14: 1; copy number 92: 4.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:239,085,827–239,085,926, 1 gene (within-gene range 0–1): MIR4441.
- chr3:50,419,781–50,419,899, 1 gene (within-gene range 0–1): RNA5SP131.
- chr6:33,694,293–33,746,905, 3 genes (within-gene range 0–2): UQCC2, MIR3934, IP6K3.
- chr10:42,871,521–42,874,060, 1 gene: LINC02623.
- chr10:86,052,448–86,052,566, 1 gene (within-gene range 0–1): RNA5SP322.
- chr13:48,488,963–48,578,088, 5 genes: RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.
- chr14:98,925,137–98,927,805, 1 gene: AL132796.2.
- chr15:21,298,233–21,946,641, 37 genes: AC068446.2, RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.
- chr15:32,461,666–32,461,809, 1 gene: AC135983.5.
- chr15:40,217,428–40,277,487, 6 genes (within-gene range 0–1): PAK6, BUB1B-PAK6, AC020658.4, AC020658.3, AC020658.7, C15orf56.
- chr16:35,207,903–35,222,048, 2 genes (within-gene range 0–1): TP53TG3GP, RARRES2P5.
- chr16:35,574,834–35,575,494, 1 gene: C1QL1P1.
- chr21:42,974,510–43,076,943, 2 genes: PKNOX1, CBS.
- chr21:43,115,334–43,115,709, 1 gene: MRPL51P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 78 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:441,498–1,728,172, 46 genes, copy number 5: EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1.
- chr5:17,156,971–17,157,071, 1 gene, copy number 5 (within-gene range 4–5): RNA5SP180.
- chr7:74,773,962–74,789,376, 1 gene, copy number 14: NCF1.
- chr7:74,843,754–74,890,610, 1 gene, copy number 5 (within-gene range 4–5): STAG3L2.
- chr11:1,991,096–2,001,470, 5 genes, copy number 5–92: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr15:21,951,242–21,951,323, 1 gene, copy number 6: MIR5701-3.
- chr15:21,990,074–22,095,857, 5 genes, copy number 7 (within-gene range 2–36): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P.
- chr15:22,070,241–22,095,472, 2 genes, copy number 7 (within-gene range 7–36): OR4M2, OR4N4.
- chr15:22,178,107–22,185,402, 2 genes, copy number 8: IGHV1OR15-3, IGHV4OR15-8.
- chr15:32,313,126–32,367,784, 2 genes, copy number 8: AC139426.1, AC139426.2.
- chr15:32,398,956–32,446,964, 5 genes, copy number 6–10 (within-gene range 4–10): AC135983.1, ULK4P1, U8, DNM1P32, RN7SL539P.
- chr21:43,092,956–43,107,570, 1 gene, copy number 11: U2AF1.
- chr21:44,133,610–44,240,966, 6 genes, copy number 11: GATD3A, LINC01678, AP001056.2, AP001056.1, AP001057.1, ICOSLG.

Autosomal genes at a single copy (total copy number 1): 16,267. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
